Somatic mutation profile of tumor specimen 0DM4XL from CCDI case PBCAAM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.5 years (9,316 days).
Specimen 0DM4XL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612733c0-9436-484a-a8bc-cda79bb1039e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cceeb80-4725-4b73-8ab4-dec35618d6f8

The open-access MAF lists 68 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 13, 3'UTR 3, 5'UTR 3, Nonsense Mutation 2, Intron 2, Splice Site 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 124/363 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 147/532 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 558/921 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AQP10 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 72/898 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.617); catalogued as rs377590602; called by muse, mutect2
- ARHGAP26 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 82/1087 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV50844027; called by muse, mutect2
- BNC2 | c.1342A>G p.K448E | Missense Mutation (SNP) | VAF 164/542 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104432515; called by muse, mutect2, varscan2
- CWC27 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 77/1123 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101126612; called by muse, mutect2
- GNAT3 | c.942del p.E315Kfs*9 | Frame Shift Del (DEL) | VAF 223/1210 reads (18%) | catalogued as rs748562154; called by mutect2, pindel, varscan2
- KCTD9 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 72/1204 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1180623628, COSV55339367; called by muse, mutect2
- MAOA | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 34/1110 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV58642400, COSV58643545; called by muse, mutect2
- NFXL1 | c.2672T>G p.L891R | Missense Mutation (SNP) | VAF 272/1527 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101040113; called by muse, mutect2, varscan2
- OR3A1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 195/1097 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs368453639; called by muse, mutect2, varscan2
- PCSK6 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.018); catalogued as rs1036740550; called by muse, mutect2
- RASSF9 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 35/1083 reads (3%) | catalogued as COSV100771549, COSV63435941; called by muse, mutect2
- SEMA4D | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 143/901 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as rs767629842; called by muse, mutect2, varscan2
- SLC25A27 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 293/895 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs200548509, COSV99243069; called by muse, mutect2, varscan2
- TENM2 | c.7493C>T p.P2498L (on ENST00000518659 / NM_001122679.2; = p.P2259L on NM_001080428.3) | Missense Mutation (SNP) | VAF 38/1374 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101319366; called by muse, mutect2
- TEX13B | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 54/862 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1274445671; called by muse, mutect2
- UBE3C | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 60/1136 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61955240; called by muse, mutect2
- BTBD8 | c.3578C>G p.A1193G (on ENST00000636805 / NM_001376131.1; = p.A680G on NM_015237.4) | Missense Mutation (SNP) | VAF 79/1364 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); called by muse, mutect2
- C10orf120 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 33/701 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.31); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 46/1472 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- C1QTNF12 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 84/1108 reads (8%) | called by muse, mutect2
- C20orf96 | c.425T>C p.L142P (on ENST00000360321 / NM_153269.3; = p.L141P on NM_080571.1) | Missense Mutation (SNP) | VAF 22/371 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); called by muse, mutect2
- CAPG | c.383C>G p.T128S | Missense Mutation (SNP) | VAF 198/717 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD2 | c.821A>C p.Q274P | Missense Mutation (SNP) | VAF 146/838 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP4F11 | c.551A>T p.E184V | Missense Mutation (SNP) | VAF 66/852 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2
- DOCK8 | c.5963G>T p.G1988V | Missense Mutation (SNP) | VAF 156/470 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD3 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 183/540 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HEPH | c.2897C>A p.A966E (on ENST00000343002; = p.A699E on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 223/773 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KCND1 | c.646A>G p.R216G | Missense Mutation (SNP) | VAF 154/602 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- LVRN | c.2854A>G p.M952V | Missense Mutation (SNP) | VAF 267/1026 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- MALRD1 | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 67/1360 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); called by muse, mutect2
- OBSCN | c.5081G>A p.G1694E | Missense Mutation (SNP) | VAF 47/770 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8K1 | c.542G>C p.S181T | Missense Mutation (SNP) | VAF 36/1172 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.127); called by muse, mutect2
- PDE11A | c.413A>C p.D138A | Missense Mutation (SNP) | VAF 299/873 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RECQL4 | c.1666G>T p.G556C | Missense Mutation (SNP) | VAF 201/1357 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHEX | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 28/795 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2
- SCIMP | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 42/812 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SCYL2 | c.1370T>C p.L457P | Missense Mutation (SNP) | VAF 66/1097 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SENP7 | c.2309T>C p.L770S | Missense Mutation (SNP) | VAF 32/1273 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SKIDA1 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 60/449 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SLFN13 | c.2098A>G p.I700V | Missense Mutation (SNP) | VAF 70/981 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); called by muse, mutect2
- SMARCA4 | c.2575A>G p.T859A | Missense Mutation (SNP) | VAF 64/854 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNRK | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 51/796 reads (6%) | called by muse, mutect2
- THSD7A | c.1456T>C p.S486P | Missense Mutation (SNP) | VAF 112/607 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRPM3 | c.807+5G>T | Splice Region (SNP) | VAF 46/1522 reads (3%) | called by muse, mutect2
- DNAH7 | c.4749A>G p.Q1583= | Silent (SNP) | VAF 64/1324 reads (5%) | called by muse, mutect2
- GSDMD | c.543G>A p.S181= | Silent (SNP) | VAF 320/752 reads (43%) | catalogued as rs779813692; called by muse, mutect2, varscan2
- HTATIP2 | c.393C>T p.S131= | Silent (SNP) | VAF 230/970 reads (24%) | called by muse, mutect2, varscan2
- MLF1 | c.564T>C p.N188= | Silent (SNP) | VAF 56/884 reads (6%) | called by muse, mutect2
- MYH2 | c.4174C>T p.L1392= | Silent (SNP) | VAF 694/1138 reads (61%) | called by muse, mutect2, varscan2
- NOMO1 | c.2401C>T p.L801= | Silent (SNP) | VAF 82/1421 reads (6%) | called by muse, mutect2
- OR9Q2 | c.264C>T p.H88= | Silent (SNP) | VAF 222/620 reads (36%) | catalogued as rs761516412, COSV100285496; called by muse, mutect2, varscan2
- PCNX2 | c.909A>C p.S303= | Silent (SNP) | VAF 81/482 reads (17%) | called by muse, mutect2, varscan2
- PPP1R3A | c.2298C>T p.I766= | Silent (SNP) | VAF 174/996 reads (17%) | catalogued as rs752856039, COSV99494358; called by muse, varscan2
- RAB39B | c.435C>T p.Y145= | Silent (SNP) | VAF 36/1380 reads (3%) | catalogued as rs376181426, COSV65624655; called by muse, mutect2
- SMPD3 | c.1695C>T p.P565= | Silent (SNP) | VAF 44/723 reads (6%) | catalogued as rs763060796, COSV99545113; called by muse, mutect2
- USP17L4 | c.1389A>C p.V463= | Silent (SNP) | VAF 59/199 reads (30%) | called by muse, mutect2, varscan2
- YY2 | c.126C>T p.Y42= | Silent (SNP) | VAF 40/1099 reads (4%) | catalogued as COSV63412856; called by muse, mutect2
- CISD3 | c.*67G>A | 3'UTR (SNP) | VAF 27/493 reads (5%) | called by muse, mutect2
- CTNND2 | c.-76A>C | 5'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- KCNC4 | c.*26A>C | 3'UTR (SNP) | VAF 89/445 reads (20%) | called by muse, mutect2, varscan2
- KIF26B | c.*85A>G | 3'UTR (SNP) | VAF 48/294 reads (16%) | called by muse, mutect2, varscan2
- MPP5 | c.576+87A>G | Intron (SNP) | VAF 30/131 reads (23%) | catalogued as rs967284082; called by muse, mutect2, varscan2
- PRDM13 | c.-33C>G | 5'UTR (SNP) | VAF 47/379 reads (12%) | called by muse, mutect2, varscan2
- TBCK | c.-148G>A | 5'UTR (SNP) | VAF 88/286 reads (31%) | called by muse, mutect2, varscan2
- WDR12 | c.1122-53G>C | Intron (SNP) | VAF 34/374 reads (9%) | catalogued as rs928623855; called by muse, mutect2
